Somatic mutation profile of tumor specimen HTMCP-03-06-02343-01A (aliquot HTMCP-03-06-02343-01A-01D-9392) from CGCI case HTMCP-03-06-02343, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5df2080-d2af-4b57-bf7b-4874e03717d4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02343-10A (Blood Derived Normal), aliquot HTMCP-03-06-02343-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a42ba3e0-7130-4406-bca0-0ed50509e169

The open-access MAF lists 187 somatic variants for this specimen: 128 protein-altering or splice-affecting, 47 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 47, Nonsense Mutation 18, Intron 8, Splice Region 2, 3'UTR 1, RNA 1, 5'UTR 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.3187C>T p.Q1063* | Nonsense Mutation (SNP) | VAF 32/153 reads (21%) | catalogued as rs876657678, COSV66451422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV54062992, COSV54071143; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.632-1G>C p.X211_splice | Splice Site (SNP) | VAF 33/118 reads (28%) | catalogued as rs398124177, CS982354; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as rs769707860; called by muse, mutect2, varscan2
- AK9 | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as COSV100393750; called by muse, mutect2, varscan2
- AKAP8 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs201405913, COSV54103203; called by muse, mutect2, varscan2
- ANKS1B | c.2594G>T p.R865I (on ENST00000547776 / NM_152788.4; = p.R91I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60362771; called by muse, mutect2, varscan2
- ARHGAP35 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1054531443; called by muse, mutect2, varscan2
- ASPM | c.8615C>T p.T2872M | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs142176273; called by muse, mutect2, varscan2
- BCL9 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs782485553; called by muse, mutect2, varscan2
- BRCA2 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.911); catalogued as COSV66453684; called by muse, mutect2, varscan2
- CFAP100 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV61502562; called by muse, varscan2
- COG7 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV56151293; called by muse, mutect2, varscan2
- COPA | c.2773C>A p.Q925K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99615035; called by muse, mutect2, varscan2
- CSF2RA | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs761350119; called by muse, mutect2, varscan2
- DDX41 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746011550, COSV57253707; called by muse, mutect2, varscan2
- DENND1A | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs150150301; called by muse, mutect2, varscan2
- DOCK9 | c.2951G>A p.R984Q (on ENST00000376460 / NM_001366676.2; = p.R985Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1323738459, COSV59635000; called by muse, mutect2
- EPC1 | c.1252G>C p.D418H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53922723; called by muse, mutect2, varscan2
- EPHA5 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV56659182; called by muse, mutect2, varscan2
- FAT2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV55825486; called by muse, mutect2, varscan2
- FLG2 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 93/555 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs866959242; called by muse, mutect2, varscan2
- GIGYF1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99308602; called by muse, mutect2, varscan2
- HIVEP2 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV50041608, COSV99172241; called by muse, mutect2, varscan2
- IGF2R | c.7330C>T p.Q2444* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV63631176; called by muse, mutect2, varscan2
- KMT2C | c.4432C>T p.Q1478* | Nonsense Mutation (SNP) | VAF 35/134 reads (26%) | catalogued as COSV51297329; called by muse, mutect2, varscan2
- LRP5 | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs573492210; called by muse, mutect2, varscan2
- LRRC7 | c.1168C>A p.L390I (on ENST00000651989 / NM_001370785.2; = p.L357I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50653148; called by muse, mutect2, varscan2
- LRRCC1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1400711958; called by muse, mutect2, varscan2
- LTBP1 | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100616821; called by muse, mutect2, varscan2
- MAST3 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767566791; called by muse, mutect2, varscan2
- MUC21 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 91/500 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs1452969622; called by muse, mutect2, varscan2
- MYH2 | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.347); catalogued as COSV55431167; called by muse, mutect2, varscan2
- NALCN | c.2905C>G p.L969V | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as COSV99215798; called by muse, mutect2, varscan2
- NRDC | c.2625C>G p.I875M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV61409613; called by muse, mutect2, varscan2
- NWD1 | c.3601G>A p.D1201N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs755839382; called by muse, mutect2, varscan2
- PARP14 | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV71734578, COSV71734764; called by muse, mutect2, varscan2
- PCDHGB1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV53908272; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs61729308, COSV100982277; called by muse, mutect2
- RADX | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV65320450; called by muse, mutect2, varscan2
- ROS1 | c.5845C>T p.L1949F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.617); catalogued as COSV63856701; called by muse, mutect2, varscan2
- SCN7A | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV69271323; called by muse, mutect2, varscan2
- SETD1A | c.3647C>A p.S1216Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52688965; called by muse, mutect2
- SH3PXD2B | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs753379729; called by muse, mutect2, varscan2
- TNN | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1364908404, COSV53426848; called by muse, mutect2, varscan2
- TRERF1 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs769439387, COSV61674127; called by muse, mutect2, varscan2
- ZFHX3 | c.10928C>T p.S3643L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51739070, COSV99213843; called by muse, mutect2, varscan2
- ZNF23 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs963163414; called by muse, mutect2, varscan2
- ZNF236 | c.4774C>T p.Q1592* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV53483633; called by muse, mutect2, varscan2
- ZNF536 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV62818555; called by muse, mutect2, varscan2
- ZNF571 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV60733023; called by muse, mutect2, varscan2
- ACSL6 | c.1248C>G p.F416L (on ENST00000379240; = p.F441L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADA | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRG4 | c.4751G>C p.R1584T | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP9 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7369C>T p.Q2457* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | called by muse, mutect2, varscan2
- APLP1 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ARID1A | c.2050C>G p.H684D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ASPM | c.3568C>G p.L1190V | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ATG2B | c.5780G>C p.R1927T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ATP11B | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BMPER | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- BRSK1 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- BTBD8 | c.4784C>G p.S1595C (on ENST00000636805 / NM_001376131.1; = p.S1082C on NM_015237.4) | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C2orf16 | c.3383C>T p.S1128L | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CACNA2D2 | c.2936+3G>A | Splice Region (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.1080C>G p.I360M | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC171 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CFAP100 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- CFAP100 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.332); called by muse, varscan2
- COL4A6 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DNAH7 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK8 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 217/260 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DOCK8 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 52/492 reads (11%) | called by muse, mutect2, varscan2
- FANCM | c.5450G>A p.G1817E | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL5 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, varscan2
- GCKR | c.666G>C p.W222C | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- GIGYF1 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNPTAB | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GPATCH8 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- GPRC6A | c.2669C>A p.A890E | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGSF21 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- IRF5 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ITPR1 | c.3038C>T p.S1013F (on ENST00000354582; = p.S998F on NM_002222.7) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KCND1 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KDM5B | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.10660G>C p.D3554H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF13B | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF24 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 71/737 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2
- KLF5 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KMT2C | c.14083C>A p.P4695T | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LARP1B | c.807C>G p.I269M | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- LRCH3 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- LRP1B | c.7331C>T p.S2444F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- LY75 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2, varscan2
- MAP3K15 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MYH4 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MYO1C | c.2611-3C>T | Splice Region (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- NACAD | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NID2 | c.4121G>T p.R1374I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, varscan2
- NLRP2 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- NOL8 | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NUP155 | c.2557G>C p.D853H (on ENST00000231498 / NM_153485.3; = p.D794H on NM_004298.4) | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PCDH19 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PLXNB2 | c.5116G>T p.E1706* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PTPRU | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RBM6 | c.3133G>C p.D1045H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RUFY3 | c.257C>A p.S86* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- SMC1A | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPATA16 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SYNE1 | c.11350G>C p.E3784Q (on ENST00000367255 / NM_182961.4; = p.E3769Q on NM_033071.3) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TAF1L | c.4642C>G p.H1548D | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLL1 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- TPR | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TRAK2 | c.1551G>C p.Q517H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TRIM33 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- TRIO | c.4694C>G p.S1565* | Nonsense Mutation (SNP) | VAF 22/197 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.99480G>C p.K33160N (on ENST00000591111; = p.K25736N on NM_003319.4) | Missense Mutation (SNP) | VAF 44/182 reads (24%) | PolyPhen benign (0.092); called by muse, mutect2, varscan2
- VCAN | c.4892C>T p.S1631L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA3B | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- WBP4 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- WDFY4 | c.9523G>A p.G3175R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK1 | c.5630C>G p.S1877* (on ENST00000315939 / NM_018979.4; = p.S1629* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- WNK1 | c.5756C>T p.S1919L (on ENST00000315939 / NM_018979.4; = p.S1671L on NM_014823.3) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF350 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, varscan2
- ZNF473 | c.1985C>G p.S662* | Nonsense Mutation (SNP) | VAF 33/161 reads (20%) | called by muse, mutect2, varscan2
- ABCC1 | c.2922C>T p.I974= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ABCC2 | c.2838G>A p.V946= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- BAZ2A | c.768C>T p.V256= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs758948518, COSV51634644; called by muse, mutect2, varscan2
- CACNA1S | c.2742G>A p.L914= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs752740321; called by muse, mutect2, varscan2
- CACNA2D3 | c.3138G>A p.Q1046= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV55521362; called by muse, mutect2, varscan2
- CEP152 | c.1017G>A p.L339= | Silent (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- CHD7 | c.1959G>A p.P653= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs747024874, COSV71110367; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNTNAP1 | c.390G>A p.S130= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV52851772; called by muse, mutect2, varscan2
- COL18A1 | c.1746C>T p.L582= (on ENST00000359759 / NM_130444.3; = p.L347= on NM_030582.4) | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- CSF2RA | c.765G>A p.L255= | Silent (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- EPB41L2 | c.1953C>G p.L651= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs1337718262; called by muse, mutect2, varscan2
- FOXA2 | c.1206C>G p.L402= (on ENST00000377115 / NM_153675.3; = p.L408= on NM_021784.5) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1448516922; called by muse, mutect2
- GPC6 | c.546C>T p.F182= | Silent (SNP) | VAF 49/415 reads (12%) | catalogued as COSV65515974; called by muse, mutect2, varscan2
- GREB1L | c.93G>A p.V31= | Silent (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- GRIN2B | c.1218G>C p.L406= | Silent (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- GTF2F1 | c.1515G>A p.K505= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- JUND | c.840C>T p.I280= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1292070305; called by muse, mutect2, varscan2
- LGI4 | c.1191C>T p.F397= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1379988786, COSV59534934; called by muse, mutect2
- LRTM2 | c.240G>T p.L80= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- MAML1 | c.1962C>T p.L654= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs367701959; called by muse, mutect2, varscan2
- MAST3 | c.1653G>A p.V551= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1432204007; called by muse, mutect2, varscan2
- MCM3AP | c.3945C>G p.L1315= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- MLNR | c.180G>T p.V60= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- MYO1C | c.2901C>A p.I967= (on ENST00000648651 / NM_001080779.2; = p.I932= on NM_033375.5) | Silent (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- MYRIP | c.117G>A p.L39= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- NRAS | c.569A>G p.*190= | Silent (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- PCDH19 | c.1809C>T p.V603= | Silent (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1362C>T p.F454= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs969018075, COSV56545846; called by muse, mutect2, varscan2
- PCDHA13 | c.1671C>T p.D557= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs782266148, COSV56480434; called by muse, mutect2, varscan2
- PRKDC | c.9549C>T p.I3183= | Silent (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- PRPF3 | c.1581C>T p.V527= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV100254682; called by muse, mutect2, varscan2
- SAMD9 | c.177C>T p.I59= | Silent (SNP) | VAF 60/256 reads (23%) | catalogued as COSV66076954; called by muse, mutect2, varscan2
- SAMD9L | c.1971A>G p.E657= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.1080C>T p.F360= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.177C>T p.L59= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- SORCS3 | c.1602G>A p.L534= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- SPTAN1 | c.2604G>C p.L868= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV63988505; called by muse, mutect2, varscan2
- SPTAN1 | c.5658C>T p.I1886= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV63989230; called by muse, mutect2, varscan2
- ST6GAL2 | c.210G>A p.P70= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1363743593, COSV64526171, COSV64531672; called by muse, mutect2
- TGFBI | c.1437C>T p.I479= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs776535345, COSV100526213; called by muse, mutect2, varscan2
- TIE1 | c.2790G>A p.R930= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- TMC4 | c.2115G>A p.L705= (on ENST00000617472 / NM_001145303.3; = p.L699= on NM_144686.4) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV55366539; called by muse, mutect2
- TTC16 | c.1092G>A p.E364= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1278241229; called by muse, mutect2
- ULK4 | c.2865C>T p.L955= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as rs766866767; called by muse, mutect2, varscan2
- ZNF18 | c.60C>T p.D20= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1446655709; called by muse, mutect2, varscan2
- ZNF425 | c.1863C>G p.L621= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- ZNF613 | c.105C>T p.D35= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs766471007, COSV53272960; called by muse, mutect2, varscan2
- AL049777.1 | n.510+4461C>G | Intron (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- AQP7 | c.*637G>A | 3'UTR (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- CYTH3 | c.449+866C>T | Intron (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-129645C>G | Intron (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-14969G>A | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as rs915278371; called by muse, mutect2, varscan2
- MUC19 | n.19986C>T | RNA (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.2424+25_2424+28del | Intron (DEL) | VAF 16/70 reads (23%) | catalogued as rs759014851; called by pindel, varscan2
- PRR12 | chr19:49591684 C>T | 5'Flank (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.1280+3945C>T | Intron (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- TJP2 | c.61-7271C>T | Intron (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+5311G>T | Intron (SNP) | VAF 35/148 reads (24%) | catalogued as COSV100629454; called by muse, mutect2, varscan2
- UNC45A | c.-5C>A | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
